Surgical pathology report (de-identified scan), TCGA case TCGA-D1-A0ZR, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site Mayo Clinic, specimen TCGA-D1-A0ZR-01A (Primary Tumor).

[page 1 of 6]
Adenocarcinoma, endometrioid, NOS
8380/3

Site Code: endometrium c54.1

1/17/11 *lee*

DIAGNOSIS:

B. Uterus, left and right ovaries and fallopian tubes, hysterectomy and bilateral salpingo-oophorectomy: FIGO grade II (of III) endometrial adenocarcinoma, endometrioid type, forming a 3.4 x 2.7 x 1.6 cm polypoid mass in the posterior and right lateral wall of the endometrial cavity. The tumor invades 0.2 cm into a 1.7 cm thick myometrial wall. The lower uterine segment is not involved. Cervix shows no diagnostic abnormalities. Ovaries and fallopian tubes show no diagnostic abnormalities.

A. Abdomen, panniculectomy: Skin and subcutaneous tissue, 5015.0 grams, identified grossly.

C. D. E. F. Lymph nodes, left pelvic, excision: Multiple (2 internal iliac, 5 external iliac, 3 common iliac, 12 obturator) left pelvic lymph nodes are negative for tumor.

G. H. I. J. Lymph nodes, right pelvic, excision: Multiple (8 external iliac, 3 internal iliac, 6 common iliac, 9 obturator) right pelvic lymph nodes are negative for tumor.

K. N. Gonadal vessels, right and left, excisions: Negative for tumor, bilaterally.

L. M. Lymph nodes, left para-aortic, excision: Multiple (5 above the inferior mesenteric artery and 2 below the inferior mesenteric artery) left para-aortic lymph nodes are negative for tumor.

O. P. Lymph nodes, right para-aortic, excision: Multiple (8 above

[page 2 of 6]
the inferior mesenteric artery and 2 below the inferior mesenteric artery) right para-aortic lymph nodes are negative for tumor.

This final pathology report is based on the gross/macrosopic examination and frozen section histologic evaluation of the specimen(s).

GROSS DESCRIPTION:

A. Received fresh labeled "pannus" is a 5015.0 gram portion of skin and subcutaneous tissue, with umbilicus. No lesions identified.

Gross examination only.

B. Received fresh labeled "uterus, left and right tubes and ovaries" is a 125.0 gram uterus with attached bilateral tubes and ovaries and an unremarkable cervix. The uterine serosa is smooth.

There is a 3.4 x 2.7 x 1.6 cm polypoid mass in the posterior and right lateral wall of the endometrial cavity with 1.7 cm myometrial thickness. There are no uterine leiomyoma present. There is a 2.7

x 1.3 x 1.2 cm right ovary with a smooth outer surface and a solid

cut surface with a 7.2 x 0.7 cm right fallopian tube. There is a 2.5

x 1.2 x 1.2 cm left ovary with a smooth outer surface and a solid

cut surface with a 8.3 x 0.7 cm left fallopian tube.

Representative sections submitted.

[page 3 of 6]
C. Received fresh labeled "left pelvic internal iliac lymph nodes"
is a 2.5 x 2.0 x 0.7 cm aggregate of adipose and lymphatic tissue.

All lymphatic tissue submitted.

D. Received fresh labeled "left pelvic external iliac lymph nodes"
is a 9.5 x 6.0 x 1.5 cm aggregate of adipose and lymphatic tissue.

All lymphatic tissue submitted.

E. Received fresh labeled "left pelvic obturator lymph nodes" is a
9.5 x 6.5 x 1.5 cm aggregate of adipose and lymphatic tissue. All

lymphatic tissue submitted.

F. Received fresh labeled "left pelvic common iliac lymph nodes" is
a 4.5 x 3.5 x 1.5 cm aggregate of adipose and lymphatic tissue. All

lymphatic tissue submitted.

G. Received fresh labeled "right pelvic external iliac lymph nodes"
is a 7.5 x 6.0 x 2.0 cm aggregate of adipose and lymphatic tissue.

All lymphatic tissue submitted.

H. Received fresh labeled "right pelvic internal iliac lymph nodes"
is a 4.0 x 2.5 x 1.0 cm aggregate of adipose and lymphatic tissue.

All lymphatic tissue submitted.

I. Received fresh labeled "right pelvic common iliac lymph nodes"
is a 3.5 x 2.0 x 1.5 cm aggregate of adipose and lymphatic tissue.

All lymphatic tissue submitted.

J. Received fresh labeled "right pelvic obturator lymph nodes" is a
6.0 x 4.0 x 2.5 cm aggregate of adipose and lymphatic tissue. All

lymphatic tissue submitted.

[page 4 of 6]
K. Received fresh labeled "left gonadal vessel" is a 6.5 cm in length by 0.4 cm in diameter portion of unremarkable blood vessel. A representative section is submitted.

L. Received fresh labeled "left para-aortic lymph nodes above the inferior mesenteric artery" is a 4.5 x 3.0 x 1.5 cm aggregate of adipose and lymphatic tissue. All lymphatic tissue submitted.
Grossed by .

M. Received fresh labeled "left para-aortic lymph nodes below the inferior mesenteric artery" is a 3.0 x 1.5 x 1.2 cm aggregate of adipose and lymphatic tissue. All lymphatic tissue submitted.

N. Received fresh labeled "right gonadal vessel" is a 5.5 cm in length by 0.5 cm in diameter portion of unremarkable blood vessel.
A representative section is submitted.

O. Received fresh labeled "right para-aortic lymph nodes above the inferior mesenteric artery" is a 5.0 x 4.0 x 2.0 cm aggregate of adipose and lymphatic tissue. All lymphatic tissue submitted.

P. Received fresh labeled "right para-aortic lymph nodes below the inferior mesenteric artery" is a 4.5 x 2.8 x 1.5 cm aggregate of adipose and lymphatic tissue. All lymphatic tissue submitted.

[page 5 of 6]
BLOCK SUMMARY:

Part A: Pannus

Part B: Uterus, left & right tubes & ovaries

- 1 Right tube
- 2 Right ovary-1
- 3 Right ovary-2
- 4 Left tube
- 5 Left ovary-1
- 6 Left ovary-2
- 7 Endometrium-1
- 8 Endometrium-2
- 9 Endometrium-3
- 10 Endometrium-4
- 11 Lower uterine segment
- 12 Cervix

Part C: Left Pelvic Lymph Nodes internal

- 1 Left internal LNS 2

Part D: Left Pelvic Lymph Nodes external

- 1 Left external LN 1
- 2 Left external LN 1
- 3 Left external LNS 2
- 4 Left external LN 1

Part E: Left Pelvic Lymph Nodes obturator

- 1 Left obturator LNS 2
- 2 Left obturator LNS 3
- 3 Left obturator LNS 2
- 4 Left obturator LN 1
- 5 Left obturator LNS 3
- 6 Left obturator LN 1

Part F: Left Pelvic Lymph Nodes common

- 1 Left common LNS 2
- 2 Left common LN 1

Part G: Right Pelvic Lymph Nodes external

- 1 Rt external LNs 1

[page 6 of 6]
- 2 Rt external LNs (1of2)
- 3 Rt external LNs (2of2)
- 4 Rt external LNs 2
- 5 Rt external LNs 1
- 6 Rt external LNs 3

Part H: Right Pelvic Lymph Nodes internal

- 1 Right internal LNS 2
- 2 Right internal LN 1

Part I: Right Pelvic Lymph Nodes common

- 1 Right common LN 1
- 2 Right common LNS 2
- 3 Right common LN 1

Part J: Right Pelvic Lymph Nodes obturator

- 1 Right obturator LNS 3
- 2 Right obturator LN 1
- 3 Right obturator LNS 2
- 4 Right obturator LN 1
- 5 Right obturator LN 1
- 6 Right obturator LN 1

Part K: Left Gonadal vessels

- 1 Left gonadal vessels

Part L: Left Para-aortic Lymph Nodes above IMA

- 1 Lt above IMA LNs 2
- 2 Lt above IMA LNs 2
- 3 Lt above IMA LNs 1

Part M: Left Para-aortic Lymph Nodes below IMA

- 1 Lt below IMA LNs 1
- 2 Lt below IMA LNs 1

Part N: Right Gonadal vessels

- 1 Right gonadal vessels

Part O: Right Para-aortic Lymph Nodes above IMA

- 1 Rt above IMA LNS 3
- 2 Rt above IMA LNS 2
- 3 Rt above IMA LN 1

Part P: Right Para-aortic Lymph Nodes below IMA

- 1 Rt below IMA LN 1
- 2 Rt below IMA LN (1of2)
- 3 Rt below IMA LN (2of2)

IIHAA Discrepancy		☒

Source: NCI Genomic Data Commons file 6d4cf9c5-3eb5-420d-a804-746745d46f48 (TCGA-D1-A0ZR.ECC5B77F-7B6C-4C4A-A32C-1346DC3AF24D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).